Somatic mutation profile of tumor specimen TCGA-OR-A5LJ-01A (aliquot TCGA-OR-A5LJ-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LJ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 54.9 years (20,069 days).
Specimen TCGA-OR-A5LJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4c19f1b-7db6-47d9-959d-12dad74174b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LJ-10A (Blood Derived Normal), aliquot TCGA-OR-A5LJ-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10a0ec35-8ffc-4e59-9d88-f39d5e388866

The open-access MAF lists 418 somatic variants for this specimen: 313 protein-altering or splice-affecting, 101 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 101, Frame Shift Del 52, Nonsense Mutation 12, In Frame Del 9, Frame Shift Ins 7, Splice Site 4, Splice Region 3, Intron 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 64/134 reads (48%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 89/101 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- LDLR | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879254715, CM162617, CM970882; ClinVar: pathogenic; called by muse, mutect2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 30/39 reads (77%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 106/123 reads (86%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6248C>T p.S2083F (on ENST00000272895 / NM_173076.3; = p.S1765F on NM_015657.3) | Missense Mutation (SNP) | VAF 151/186 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55955359; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 124/150 reads (83%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCC1 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 51/60 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs45517537, COSV60681773; called by muse, mutect2, varscan2
- AC093155.3 | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 114/134 reads (85%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1446002662; called by muse, mutect2, varscan2
- ADCY6 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374045751; called by muse, mutect2, varscan2
- ADH7 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 94/118 reads (80%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs757367262, COSV52921077; called by muse, mutect2, varscan2
- AKR1D1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs537010232, COSV54336148; called by muse, mutect2, varscan2
- ALS2CL | c.1768G>A p.V590M | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs200208936, COSV100014623; called by muse, mutect2, varscan2
- ANGPT2 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs370206079; called by muse, mutect2, varscan2
- ANKFY1 | c.3392G>A p.R1131H (on ENST00000341657 / NM_001330063.2; = p.R1132H on NM_016376.5) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763606938; called by mutect2, varscan2
- ANOS1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1176399589, COSV52918865; called by muse, mutect2
- ANOS1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 103/133 reads (77%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as rs894572813; called by muse, mutect2, varscan2
- AP4M1 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.135); catalogued as rs201065427, COSV57997352; called by muse, mutect2, varscan2
- ARAP2 | c.4793_4794del p.K1598Rfs*6 | Frame Shift Del (DEL) | VAF 29/35 reads (83%) | catalogued as rs1560356072; called by mutect2, pindel, varscan2
- ARHGAP21 | c.5569C>T p.R1857C | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs774267791; called by muse, mutect2, varscan2
- ARHGAP35 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs142807428; called by muse, mutect2, varscan2
- ARRDC1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as rs760915494, COSV58380530; called by muse, mutect2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 21/30 reads (70%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASMTL | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 71/84 reads (85%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs754253340; called by muse, mutect2, varscan2
- ASXL3 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 69/80 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV52482180; called by muse, mutect2, varscan2
- ATAD5 | c.3893C>T p.A1298V | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1387589675; called by muse, varscan2
- ATP2B3 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 83/99 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs782601191; called by muse, mutect2, varscan2
- ATP8B3 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 93/103 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773757936; called by muse, mutect2, varscan2
- BDP1 | c.7664del p.N2555Ifs*35 | Frame Shift Del (DEL) | VAF 12/105 reads (11%) | catalogued as COSV62429732; called by mutect2, pindel, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BMP8B | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 139/842 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs777287046; called by muse, mutect2, varscan2
- BTN2A2 | c.69_71del p.L24del | In Frame Del (DEL) | VAF 83/101 reads (82%) | catalogued as rs751776181; called by mutect2, varscan2
- C15orf40 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 142/170 reads (84%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV58450533; called by muse, mutect2, varscan2
- C16orf86 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 126/145 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54675826; called by muse, mutect2, varscan2
- C1orf87 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 33/57 reads (58%) | catalogued as rs753805446, COSV104428142; called by muse, mutect2, varscan2
- CA3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770535043, COSV53409913; called by muse, mutect2, varscan2
- CCDC178 | c.2272C>T p.R758C (on ENST00000383096 / NM_001105528.3; = p.R720C on NM_198995.3) | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs148945908; called by muse, mutect2, varscan2
- CCT6A | c.725+1G>A p.X242_splice | Splice Site (SNP) | VAF 12/115 reads (10%) | catalogued as COSV51905746; called by muse, mutect2, varscan2
- CD99L2 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as rs1008485876; called by muse, mutect2
- CDCA7 | c.236G>A p.R79Q (on ENST00000347703 / NM_145810.3; = p.R158Q on NM_031942.5) | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs758810878; called by muse, mutect2, varscan2
- CDH4 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.453); catalogued as rs1051676; called by muse, mutect2, varscan2
- CDT1 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs750027487; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 72/83 reads (87%) | catalogued as rs778664468; called by mutect2, varscan2
- CLTC | c.2710G>A p.V904I | Missense Mutation (SNP) | VAF 84/104 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs371208527; called by muse, mutect2, varscan2
- COL18A1 | c.4991C>T p.P1664L (on ENST00000359759 / NM_130444.3; = p.P1429L on NM_030582.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs774649540; called by muse, mutect2, varscan2
- COL5A1 | c.4910G>A p.R1637H | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199998065; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COLEC10 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs771208188, COSV100250970; called by muse, mutect2
- CXCL9 | c.312del p.K104Nfs*8 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as COSV53578362; called by pindel, varscan2
- CXCR3 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1349979497, COSV65461872; called by muse, mutect2
- CXXC1 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 100/133 reads (75%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as rs760832916; called by muse, mutect2, varscan2
- CYFIP2 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1334093854, COSV59034825; called by muse, mutect2, varscan2
- CYP2F1 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 113/483 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764980124; called by muse, mutect2, varscan2
- DDX4 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.13); catalogued as rs770286750; called by muse, mutect2, varscan2
- DEF8 | c.398G>A p.R133H (on ENST00000268676 / NM_207514.3; = p.R72H on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as rs746724442; called by muse, mutect2, varscan2
- DIXDC1 | c.1439C>T p.A480V (on ENST00000440460 / NM_001037954.4; = p.A269V on NM_033425.4) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782765914; called by muse, mutect2
- DLG5 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 146/292 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772926425; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs769670477, COSV50050996; called by muse, mutect2, varscan2
- EIF3L | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 129/157 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs773704624, COSV67739904; called by muse, mutect2, varscan2
- EMC1 | c.2977C>T p.R993* | Nonsense Mutation (SNP) | VAF 37/63 reads (59%) | catalogued as rs758888994; called by muse, mutect2, varscan2
- FAM160A2 | c.2740C>T p.R914C (on ENST00000449352 / NM_001098794.2; = p.R928C on NM_032127.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as rs201012137; called by muse, mutect2, varscan2
- FBN3 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 86/151 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs141919495, COSV99561056; called by muse, mutect2, varscan2
- FBXO22 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755088177, COSV100380594; called by muse, mutect2, varscan2
- FBXW4 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140286143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | catalogued as rs748969702; called by mutect2, varscan2
- FKBP11 | c.295_296del p.L100Sfs*37 | Frame Shift Del (DEL) | VAF 50/156 reads (32%) | catalogued as rs780992567; called by pindel, varscan2
- FMR1NB | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 70/84 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs782349779; called by muse, mutect2, varscan2
- FNDC1 | c.4336C>T p.P1446S | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV51943203; called by muse, mutect2, varscan2
- FOCAD | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748492866; called by muse, mutect2, varscan2
- GET3 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs775341723; called by muse, mutect2, varscan2
- GFRA4 | c.851G>A p.R284H (on ENST00000319242 / NM_145762.3; = p.R254H on NM_022139.4) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1375386292; called by muse, mutect2, varscan2
- GNPTAB | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs761739718, COSV100172445; called by muse, mutect2, varscan2
- GPR4 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.041); catalogued as rs759097182, COSV59916190; called by muse, mutect2, varscan2
- GRINA | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 84/108 reads (78%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs371899632; called by muse, mutect2, varscan2
- HCN3 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.469); catalogued as rs756971954, COSV61362259; called by muse, mutect2, varscan2
- HELLS | c.2023C>T p.R675* | Nonsense Mutation (SNP) | VAF 86/180 reads (48%) | catalogued as COSV53295804, COSV99491988; called by muse, mutect2, varscan2
- HGFAC | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs140691145; called by muse, varscan2
- HIVEP1 | c.6839G>A p.R2280H | Missense Mutation (SNP) | VAF 89/115 reads (77%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs539555538; called by muse, mutect2, varscan2
- HOOK2 | c.776G>T p.R259M | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1217380320; called by muse, mutect2
- HOXA3 | c.1199del p.G400Vfs*104 | Frame Shift Del (DEL) | VAF 33/79 reads (42%) | catalogued as COSV100415631; called by mutect2, pindel, varscan2
- IGHG4 | c.350del p.G117Dfs*16 | Frame Shift Del (DEL) | VAF 84/142 reads (59%) | catalogued as rs1475796782; called by mutect2, pindel, varscan2
- IL17C | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs189692693; called by muse, mutect2, varscan2
- ILDR2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs768427799; called by muse, mutect2, varscan2
- IPMK | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs375383787, COSV100880242; called by muse, mutect2, varscan2
- JAK3 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs1465717926, COSV101512928; called by muse, mutect2, varscan2
- KCND1 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 104/121 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557058728; called by muse, mutect2, varscan2
- KCNH7 | c.3029C>G p.S1010C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1438445938; called by muse, mutect2
- KCNK2 | c.1232C>T p.T411M (on ENST00000444842 / NM_001017425.3; = p.T396M on NM_014217.4) | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as rs538085965; called by muse, mutect2, varscan2
- KDM6B | c.2428G>A p.V810M | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs148573983; called by muse, mutect2, varscan2
- KIF5A | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303126235; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KNTC1 | c.5332G>A p.E1778K | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs542508586; called by muse, mutect2, varscan2
- KRT71 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs771608163, COSV57291326; called by muse, mutect2, varscan2
- LGALS12 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as rs144263194; called by muse, mutect2, varscan2
- LGR6 | c.1775del p.V592Afs*10 (on ENST00000367278 / NM_001017403.1; = p.V540Afs*10 on NM_021636.3) | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs113146160, COSV55152990; called by mutect2, pindel, varscan2
- LHFPL6 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs374053260; called by muse, mutect2, varscan2
- LMLN | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 60/135 reads (44%) | catalogued as rs759582686; called by muse, mutect2, varscan2
- LOXL3 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as rs753208381; called by muse, mutect2, varscan2
- LPIN1 | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs557485971, COSV56764633; called by muse, mutect2, varscan2
- LRCH3 | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 149/311 reads (48%) | catalogued as rs1202774397, COSV100605170; called by muse, mutect2, varscan2
- LRFN2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as COSV57827803; called by muse, mutect2, varscan2
- LRRC36 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs529032150, COSV99339110; called by muse, mutect2, varscan2
- LRRC41 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as rs145805978; called by mutect2, varscan2
- LRRFIP1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 221/280 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755985867, COSV55250237; called by muse, mutect2, varscan2
- LTBP4 | c.4306C>T p.P1436S (on ENST00000308370 / NM_001042544.1; = p.P1399S on NM_003573.2) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs368212304; called by muse, mutect2, varscan2
- MAGEA11 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 150/183 reads (82%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as COSV60754362; called by muse, mutect2, varscan2
- MAP3K12 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs746760854; called by muse, mutect2
- MAST1 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1300800199, COSV52244063; called by muse, mutect2, varscan2
- MBTPS1 | c.2825C>T p.A942V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs756632031; called by muse, mutect2, varscan2
- MED23 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63436776; called by muse, mutect2, varscan2
- MIDEAS | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54093193; called by muse, mutect2, varscan2
- MORN4 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs150577682, COSV56731276; called by muse, mutect2, varscan2
- MPDZ | c.5338G>A p.V1780I | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as rs202112833; called by muse, mutect2, varscan2
- MRPL3 | c.369G>A p.Q123= | Splice Region (SNP) | VAF 44/106 reads (42%) | catalogued as rs773396692; called by muse, mutect2, varscan2
- MSH2 | c.2525_2526del p.E842Vfs*3 | Frame Shift Del (DEL) | VAF 74/132 reads (56%) | catalogued as rs587779148; called by pindel, varscan2
- MTAP | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs754550389; called by muse, varscan2
- MYO1G | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); catalogued as rs767632037, COSV51853017; called by muse, mutect2, varscan2
- NEDD4L | c.2873G>A p.R958Q (on ENST00000400345 / NM_001144967.3; = p.R938Q on NM_015277.6) | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs777624478, COSV56845561; called by muse, mutect2, varscan2
- NET1 | c.1261C>T p.R421W (on ENST00000355029 / NM_001047160.3; = p.R367W on NM_005863.5) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs139037982; called by muse, mutect2, varscan2
- NKD1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 164/205 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs763568385, COSV51691314; called by muse, mutect2, varscan2
- NLRP2 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.977); catalogued as rs561774583, COSV54753862; called by muse, mutect2, varscan2
- NME6 | c.322C>T p.R108C (on ENST00000415053; = p.R116C on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs762940733, COSV56640636; called by muse, mutect2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 42/86 reads (49%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NOD1 | c.1523del p.G508Vfs*106 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs1210143813; called by mutect2, pindel, varscan2
- NR2F1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 152/303 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as CM124382, COSV59069252; called by muse, mutect2, varscan2
- NSA2 | c.430_432del p.K144del | In Frame Del (DEL) | VAF 214/522 reads (41%) | catalogued as rs763687306; called by pindel, varscan2
- NSD3 | c.2506G>A p.G836R | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388405525; called by muse, mutect2, varscan2
- OLFML3 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs745362183; called by muse, mutect2, varscan2
- OR2A14 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV101376449, COSV101376499; called by muse, mutect2, varscan2
- PCDH15 | c.5623C>A p.P1875T | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs758308006; called by muse, varscan2
- PCDHA2 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99061489; called by muse, mutect2, varscan2
- PCDHGA3 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 164/479 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.668); catalogued as COSV53959839; called by muse, mutect2, varscan2
- PDLIM2 | c.698G>A p.R233Q (on ENST00000397760; = p.R483Q on NM_021630.6) | Missense Mutation (SNP) | VAF 134/160 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs779427808, COSV56134145; called by muse, varscan2
- PIN1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 72/119 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as rs112773610; called by muse, mutect2, varscan2
- PLCG1 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV99719558; called by muse, mutect2, varscan2
- PLIN3 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 64/83 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs760551643; called by muse, mutect2, varscan2
- PLXNA1 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as rs149327396; called by muse, mutect2, varscan2
- PLXNA1 | c.5638C>T p.R1880W | Missense Mutation (SNP) | VAF 91/434 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1368078128, COSV52530596; called by muse, mutect2, varscan2
- POP1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs747730830, COSV62894046; called by muse, mutect2, varscan2
- PPP1R16B | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs753669205; called by muse, mutect2
- PRKCI | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs762292026; called by muse, mutect2, varscan2
- PROP1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs766326238; called by muse, mutect2, varscan2
- PRR14 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as rs760368964; called by muse, mutect2, varscan2
- PSMD5 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs149552567; called by muse, mutect2, varscan2
- PVR | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs3745145, COSV51823136; called by muse, mutect2, varscan2
- RAB11B | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 198/538 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs992140697, COSV60085485; called by muse, mutect2, varscan2
- RASAL2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200438546; called by muse, mutect2, varscan2
- RASIP1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs767527552; called by muse, mutect2, varscan2
- RFFL | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs758936328, COSV99265286; called by muse, mutect2, varscan2
- RHOD | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58211362; called by muse, mutect2
- RIMBP2 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 65/70 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs751225625, COSV55475950; called by muse, mutect2, varscan2
- RIOK1 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs895470975; called by muse, mutect2, varscan2
- RNF32 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 90/167 reads (54%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs572104115; called by muse, mutect2, varscan2
- RYR1 | c.10744C>T p.R3582C | Missense Mutation (SNP) | VAF 107/223 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs768065730; called by muse, mutect2, varscan2
- SEPTIN8 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340600594; called by muse, mutect2, varscan2
- SESN1 | c.1433C>T p.A478V (on ENST00000356644 / NM_001199933.1; = p.A537V on NM_014454.3) | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57422214; called by muse, mutect2, varscan2
- SGIP1 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 56/67 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779386487, COSV52762219; called by muse, mutect2, varscan2
- SGSM3 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs376663138; called by muse, varscan2
- SIPA1L3 | c.2337dup p.I780Hfs*23 | Frame Shift Ins (INS) | VAF 32/74 reads (43%) | catalogued as rs748827733; called by mutect2, varscan2
- SLC13A2 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs782243722, COSV58997438; called by muse, mutect2, varscan2
- SLC14A1 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV58934098; called by muse, mutect2
- SLC4A10 | c.2719C>T p.R907W (on ENST00000446997 / NM_001354461.2; = p.R877W on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55796282; called by muse, mutect2
- SLITRK4 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 172/205 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62023049; called by muse, mutect2, varscan2
- SMO | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1173715127, COSV50825498; called by muse, mutect2, varscan2
- SMU1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV68139818; called by muse, mutect2, varscan2
- SOAT2 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1171615819; called by muse, mutect2
- SPINT2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 95/165 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755052415; called by muse, mutect2, varscan2
- SRMS | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs772507082, COSV53916030; called by muse, varscan2
- SRPX2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 72/83 reads (87%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs749092510; called by muse, mutect2, varscan2
- SULF2 | c.1958A>C p.K653T | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV63414536; called by muse, mutect2, varscan2
- TBXA2R | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1452513934; called by muse, mutect2, varscan2
- TDP1 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759700086, COSV59643600; called by muse, mutect2, varscan2
- TET1 | c.4513C>T p.R1505C | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65387723; called by muse, mutect2, varscan2
- TG | c.3602C>T p.T1201M | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201453011; called by muse, mutect2, varscan2
- TIMM8B | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 76/91 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs766033074, COSV54778617; called by muse, mutect2, varscan2
- TMEM40 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs201284335, COSV53145311; called by muse, mutect2, varscan2
- TNFRSF25 | c.42G>A p.A14= | Splice Region (SNP) | VAF 134/166 reads (81%) | catalogued as rs752948141; called by muse, mutect2, varscan2
- TNFRSF6B | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs1299161540; called by muse, mutect2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 48/92 reads (52%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TPO | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1296531286, COSV61100158; called by muse, mutect2, varscan2
- TRAPPC9 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1234819626; called by muse, mutect2
- TSHZ3 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs572265018, COSV53668205; called by muse, mutect2, varscan2
- TSPAN2 | c.136T>C p.S46P | Missense Mutation (SNP) | VAF 69/89 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs199774469; called by muse, mutect2, varscan2
- TSPAN7 | c.516del p.S173Afs*4 | Frame Shift Del (DEL) | VAF 119/192 reads (62%) | catalogued as rs752121179, COSV54531581; called by mutect2, pindel, varscan2
- TTBK1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs776897780; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 23/46 reads (50%) | catalogued as rs763652408; called by mutect2, varscan2
- USP42 | c.2783C>T p.A928V | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs753053527, COSV60359938; called by muse, mutect2
- VWF | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772466729, COSV54621841; called by muse, mutect2, varscan2
- ZNF251 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as rs777430092, COSV99478150; called by muse, mutect2, varscan2
- ZNF407 | c.4676G>A p.R1559H | Missense Mutation (SNP) | VAF 157/184 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55250865; called by muse, mutect2, varscan2
- ZNF470 | c.1168_1170del p.Y390del | In Frame Del (DEL) | VAF 47/141 reads (33%) | catalogued as rs769735021; called by pindel, varscan2
- ZNF563 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201356487; called by muse, mutect2
- ZNF646 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs769527983, COSV54922794; called by muse, mutect2, varscan2
- ZNF804B | c.2307A>G p.I769M | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60820734; called by muse, mutect2
- ZYX | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747069930; called by muse, mutect2
- ZZEF1 | c.5783C>T p.T1928M | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs772878926, COSV67556250; called by muse, mutect2, varscan2
- ADAMTS2 | c.1656G>A p.W552* | Nonsense Mutation (SNP) | VAF 138/262 reads (53%) | called by muse, varscan2
- AFF2 | c.82del p.R28Gfs*30 | Frame Shift Del (DEL) | VAF 128/284 reads (45%) | called by mutect2, pindel, varscan2
- APOB | c.8974G>A p.V2992I | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2
- APOD | c.7A>C p.M3L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP25 | c.1403del p.N468Mfs*98 (on ENST00000409202 / NM_001007231.3; = p.N460Mfs*98 on NM_014882.3) | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | called by mutect2, pindel, varscan2
- ARHGEF18 | c.2173_2178+1del | Frame Shift Del (DEL) | VAF 36/186 reads (19%) | called by mutect2, pindel, varscan2
- ASXL2 | c.2333dup p.V779Sfs*25 | Frame Shift Ins (INS) | VAF 36/50 reads (72%) | called by mutect2, varscan2
- ATP2A2 | c.2918_2920del p.S973del | In Frame Del (DEL) | VAF 98/251 reads (39%) | called by mutect2, pindel, varscan2
- BAG4 | c.1365del p.G456Dfs*6 | Frame Shift Del (DEL) | VAF 26/46 reads (57%) | called by mutect2, varscan2
- BMP3 | c.932del p.K311Rfs*46 | Frame Shift Del (DEL) | VAF 54/96 reads (56%) | called by pindel, varscan2
- BRPF3 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 45/49 reads (92%) | called by muse, mutect2, varscan2
- C1orf87 | c.1371G>C p.Q457H | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CCDC146 | c.756del p.V253* | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- CD3D | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 125/149 reads (84%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CDH2 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 136/163 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH8 | c.1469A>G p.N490S | Missense Mutation (SNP) | VAF 98/121 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CEP290 | c.2039_2052+5del p.X680_splice | Splice Site (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- CEP78 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2
- CHL1 | c.3544A>G p.I1182V (on ENST00000397491 / NM_001253387.1; = p.I1198V on NM_006614.4) | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNOT10 | c.1254del p.G419Efs*15 | Frame Shift Del (DEL) | VAF 42/163 reads (26%) | called by mutect2, pindel, varscan2
- COL19A1 | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 60/76 reads (79%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DAB2 | c.441dup p.A148Cfs*9 | Frame Shift Ins (INS) | VAF 32/106 reads (30%) | called by mutect2, varscan2
- DDX4 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 98/200 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- EHMT1 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- EIF4G1 | c.2510_2511del p.V837Efs*15 (on ENST00000346169 / NM_198241.3; = p.V642Efs*15 on NM_004953.5) | Frame Shift Del (DEL) | VAF 73/360 reads (20%) | called by pindel, varscan2
- EP300 | c.4785_4787del p.F1596del | In Frame Del (DEL) | VAF 42/58 reads (72%) | called by pindel, varscan2
- ERCC6 | c.1892T>G p.M631R | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERCC8 | c.99_102del p.N33Kfs*34 | Frame Shift Del (DEL) | VAF 38/90 reads (42%) | called by pindel, varscan2
- EXD3 | c.1795C>A p.L599M | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- FAM83E | c.889del p.Q297Rfs*6 | Frame Shift Del (DEL) | VAF 51/123 reads (41%) | called by mutect2, pindel, varscan2
- FMN2 | c.2181_2185del p.L728Rfs*8 | Frame Shift Del (DEL) | VAF 92/116 reads (79%) | called by mutect2, varscan2
- FOXD3 | c.481_483del p.K161del | In Frame Del (DEL) | VAF 18/182 reads (10%) | called by pindel, varscan2
- FOXJ3 | c.1044C>G p.S348R | Missense Mutation (SNP) | VAF 136/160 reads (85%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOXP1 | c.1240del p.L414* | Frame Shift Del (DEL) | VAF 17/121 reads (14%) | called by mutect2, pindel, varscan2
- FRAS1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- FRAS1 | c.5735dup p.N1912Kfs*11 | Frame Shift Ins (INS) | VAF 12/108 reads (11%) | called by mutect2, pindel
- GASK1B | c.83G>C p.S28T | Missense Mutation (SNP) | VAF 96/112 reads (86%) | SIFT tolerated (0.51); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GCC2 | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 175/209 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GMPPB | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- GON4L | c.400del p.M134* | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- GPR6 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRIN3 | c.1138del p.Q380Rfs*61 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- GRID1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HFE | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOOK3 | c.958G>C p.V320L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- HSPA5 | c.1863G>T p.K621N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.772); called by muse, mutect2
- IGHV4-61 | c.316G>C p.V106L | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.118); called by muse, varscan2
- IL7R | c.361del p.I121* | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by pindel, varscan2
- ITGA9 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.23); called by muse, varscan2
- ITIH1 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ITPR3 | c.2620G>A p.G874S | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH6 | c.2411del p.P804Qfs*17 | Frame Shift Del (DEL) | VAF 43/72 reads (60%) | called by mutect2, pindel, varscan2
- KDM7A | c.2242A>T p.T748S | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2B | c.4391_4392del p.V1464Afs*213 | Frame Shift Del (DEL) | VAF 33/247 reads (13%) | called by pindel, varscan2
- KRT76 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- LCE2B | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LCP2 | c.972G>A p.V324= | Splice Region (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- LRRC34 | c.1243G>A p.V415M (on ENST00000446859 / NM_001172779.2; = p.V383M on NM_153353.5) | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MIS18BP1 | c.3198A>T p.K1066N | Missense Mutation (SNP) | VAF 133/167 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MLX | c.336_338del p.X112_splice | Splice Site (DEL) | VAF 112/146 reads (77%) | called by pindel, varscan2
- MLXIPL | c.2335_2338del p.F779Sfs*37 | Frame Shift Del (DEL) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 59/68 reads (87%) | called by mutect2, varscan2
- MYH15 | c.509del p.P170Lfs*35 | Frame Shift Del (DEL) | VAF 15/142 reads (11%) | called by mutect2, pindel, varscan2
- MYO15A | c.7526C>T p.A2509V | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MYO3B | c.3988del p.S1330Lfs*102 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- NAV2 | c.1726A>G p.K576E (on ENST00000396087 / NM_001244963.2; = p.K553E on NM_145117.5) | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NEURL4 | c.3295T>C p.S1099P | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NEUROD4 | c.910dup p.R304Pfs*3 | Frame Shift Ins (INS) | VAF 14/141 reads (10%) | called by mutect2, varscan2
- NKAPD1 | c.757_760del p.K253Efs*9 (on ENST00000280352 / NM_001082970.2; = p.K254Efs*9 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/20 reads (85%) | called by mutect2, varscan2
- NOTCH3 | c.2612T>C p.F871S | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4Q3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2
- OR56A3 | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 68/87 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- PARP1 | c.2396C>T p.T799I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE8B | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PEG3 | c.1369T>C p.C457R | Missense Mutation (SNP) | VAF 185/378 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PI4K2A | c.1166C>G p.S389W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PIDD1 | c.1754C>T p.T585I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PKDREJ | c.5317C>T p.H1773Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLEKHG2 | c.139del p.R47Efs*9 | Frame Shift Del (DEL) | VAF 63/166 reads (38%) | called by mutect2, pindel, varscan2
- PLG | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.442); called by muse, mutect2
- PRKRIP1 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- PRR15 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMC2 | c.804del p.A269Pfs*34 | Frame Shift Del (DEL) | VAF 30/79 reads (38%) | called by mutect2, pindel, varscan2
- PTCH1 | c.2178del p.C727Vfs*19 | Frame Shift Del (DEL) | VAF 64/178 reads (36%) | called by mutect2, pindel, varscan2
- QSER1 | c.4509del p.K1503Nfs*38 (on ENST00000399302; = p.K1632Nfs*38 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 69/112 reads (62%) | called by mutect2, pindel, varscan2
- RNF208 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ROBO2 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RRP36 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- RTL9 | c.1207G>C p.V403L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.095); called by muse, mutect2
- RUFY2 | c.1726_1728del p.K576del | In Frame Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- SCEL | c.1784A>T p.Y595F (on ENST00000349847 / NM_144777.3; = p.Y575F on NM_003843.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SELP | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB2 | c.417+1G>A p.X139_splice | Splice Site (SNP) | VAF 22/31 reads (71%) | called by muse, mutect2, varscan2
- SLC35F3 | c.358G>A p.V120I (on ENST00000366617 / NM_001300845.1; = p.V189I on NM_173508.4) | Missense Mutation (SNP) | VAF 164/204 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX9 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPNS3 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 78/87 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SRPK2 | c.1750_1753del p.F584Nfs*15 | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | called by pindel, varscan2
- STAB1 | c.5302G>C p.D1768H | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAC3 | c.52_53del p.S18Lfs*6 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by pindel, varscan2
- TAF3 | c.2209_2211del p.K737del | In Frame Del (DEL) | VAF 60/146 reads (41%) | called by mutect2, pindel, varscan2
- TBC1D32 | c.103T>G p.C35G | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2
- TEAD1 | c.848del p.N283Mfs*6 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | called by mutect2, pindel, varscan2
- TEX11 | c.2326A>G p.T776A (on ENST00000344304; = p.T761A on NM_031276.3) | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TINAG | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- TNS4 | c.2098C>A p.Q700K | Missense Mutation (SNP) | VAF 72/87 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYK2 | c.260del p.P87Qfs*5 | Frame Shift Del (DEL) | VAF 138/443 reads (31%) | called by mutect2, varscan2
- UCK2 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- USP9X | c.5341G>A p.V1781I | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2
- VPS4A | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- WNT3 | c.665G>A p.W222* | Nonsense Mutation (SNP) | VAF 90/126 reads (71%) | called by muse, mutect2, varscan2
- XPO1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZDHHC17 | c.1127dup p.W377Lfs*5 | Frame Shift Ins (INS) | VAF 35/109 reads (32%) | called by mutect2, pindel, varscan2
- ZFPM2 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.1257dup p.W420Lfs*7 (on ENST00000355341 / NM_001077268.2; = p.W410Lfs*7 on NM_032850.5) | Frame Shift Ins (INS) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- ZNF263 | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF711 | c.230_232del p.I77del | In Frame Del (DEL) | VAF 42/262 reads (16%) | called by pindel, varscan2
- ZNF793 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ABCC4 | c.1677C>T p.D559= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs760295308; called by muse, mutect2, varscan2
- ABCC5 | c.87G>A p.T29= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs1253881716; called by muse, mutect2, varscan2
- ACBD3 | c.1035C>T p.S345= | Silent (SNP) | VAF 122/138 reads (88%) | catalogued as rs545965641; called by muse, mutect2, varscan2
- ACTR8 | c.558C>T p.I186= | Silent (SNP) | VAF 12/254 reads (5%) | catalogued as COSV51638019; called by muse, mutect2
- AMER2 | c.1203C>T p.P401= | Silent (SNP) | VAF 71/87 reads (82%) | catalogued as COSV100766324, COSV63439315; called by muse, mutect2, varscan2
- ARHGEF26 | c.2343C>T p.S781= | Silent (SNP) | VAF 57/446 reads (13%) | catalogued as rs999529490; called by muse, mutect2, varscan2
- ARMC2 | c.1437G>A p.T479= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as rs780014811, COSV64550664; called by muse, mutect2, varscan2
- ARMH3 | c.1671C>T p.R557= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as rs1351945275; called by muse, mutect2, varscan2
- ARSG | c.1176C>T p.S392= | Silent (SNP) | VAF 79/98 reads (81%) | catalogued as rs536459923, COSV71593212; called by muse, mutect2, varscan2
- ATM | c.2625C>T p.S875= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- ATP12A | c.408C>T p.S136= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as rs369759214; called by muse, mutect2, varscan2
- ATXN1 | c.2100C>T p.P700= | Silent (SNP) | VAF 74/89 reads (83%) | called by muse, mutect2, varscan2
- BMP7 | c.717G>A p.P239= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs368039601; called by muse, mutect2, varscan2
- BPIFB4 | c.495G>A p.A165= | Silent (SNP) | VAF 108/237 reads (46%) | catalogued as rs755057163; called by muse, mutect2, varscan2
- BRD4 | c.2193C>T p.P731= | Silent (SNP) | VAF 66/197 reads (34%) | catalogued as rs201923211; called by muse, mutect2, varscan2
- CAAP1 | c.1041G>A p.A347= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as rs769128296, COSV100445021; called by muse, mutect2, varscan2
- CAPN11 | c.963C>A p.P321= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV67237463; called by muse, mutect2, varscan2
- CCNT1 | c.2061T>C p.Y687= | Silent (SNP) | VAF 77/210 reads (37%) | catalogued as rs897330771; called by muse, mutect2, varscan2
- CDH4 | c.2385C>T p.Y795= | Silent (SNP) | VAF 77/167 reads (46%) | catalogued as rs559494744; called by muse, mutect2, varscan2
- CELSR3 | c.4647C>T p.S1549= | Silent (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- CNNM1 | c.2097C>T p.G699= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs142898303; called by muse, mutect2, varscan2
- COG7 | c.1785G>A p.L595= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100207541; called by muse, mutect2, varscan2
- COL17A1 | c.2424C>T p.I808= | Silent (SNP) | VAF 85/191 reads (45%) | catalogued as rs760954620, COSV62228604; called by muse, mutect2, varscan2
- DAP | c.225G>A p.A75= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs370396587; called by muse, mutect2, varscan2
- DENND4A | c.2199G>A p.L733= | Silent (SNP) | VAF 29/32 reads (91%) | called by muse, mutect2, varscan2
- DNAH17 | c.12474C>T p.N4158= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs375394275, COSV53149444; called by muse, mutect2, varscan2
- DOK4 | c.855C>T p.S285= | Silent (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- ELMO2 | c.12G>A p.P4= | Silent (SNP) | VAF 144/345 reads (42%) | catalogued as rs773994349, COSV51686007; called by muse, mutect2, varscan2
- EP400 | c.4347G>A p.P1449= | Silent (SNP) | VAF 56/74 reads (76%) | catalogued as rs150248915; called by muse, varscan2
- EPHB1 | c.2019C>T p.G673= | Silent (SNP) | VAF 161/378 reads (43%) | called by muse, mutect2, varscan2
- EPHB2 | c.1734G>A p.T578= (on ENST00000400191 / NM_001309193.2; = p.T579= on NM_004442.7) | Silent (SNP) | VAF 57/73 reads (78%) | catalogued as rs767310647, COSV65867445; called by muse, mutect2, varscan2
- EPHB3 | c.1887C>T p.D629= | Silent (SNP) | VAF 44/408 reads (11%) | catalogued as rs776325182, COSV57804478; called by muse, mutect2, varscan2
- ERCC4 | c.2274G>A p.L758= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV61311964; called by muse, mutect2
- FAM234A | c.1320C>T p.H440= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as rs777133130, COSV51451976; called by muse, mutect2, varscan2
- FARSA | c.1296C>T p.V432= | Silent (SNP) | VAF 59/176 reads (34%) | catalogued as rs754658085, COSV53366145; called by muse, mutect2, varscan2
- FAT3 | c.12897C>T p.C4299= | Silent (SNP) | VAF 118/147 reads (80%) | catalogued as COSV99963057; called by muse, mutect2, varscan2
- FBXW7 | c.1305T>C p.I435= (on ENST00000281708 / NM_001349798.2; = p.I355= on NM_018315.5) | Silent (SNP) | VAF 99/115 reads (86%) | called by muse, varscan2
- FCGBP | c.9291G>A p.V3097= | Silent (SNP) | VAF 56/383 reads (15%) | catalogued as rs779811244; called by muse, mutect2, varscan2
- FNDC3B | c.2637T>C p.P879= | Silent (SNP) | VAF 64/165 reads (39%) | called by muse, mutect2, varscan2
- FOXRED2 | c.759C>A p.T253= | Silent (SNP) | VAF 71/82 reads (87%) | called by muse, mutect2, varscan2
- FREM2 | c.3294G>T p.L1098= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs770880706; called by muse, mutect2, varscan2
- FSTL4 | c.972C>T p.S324= | Silent (SNP) | VAF 124/270 reads (46%) | catalogued as rs190908572; called by muse, mutect2, varscan2
- FUZ | c.900G>C p.L300= | Silent (SNP) | VAF 59/110 reads (54%) | catalogued as rs374092791; called by muse, mutect2, varscan2
- GABRR3 | c.168G>A p.A56= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as rs370488601; called by muse, mutect2, varscan2
- GNLY | c.372C>T p.A124= | Silent (SNP) | VAF 90/103 reads (87%) | catalogued as rs147680816; called by mutect2, varscan2
- GRID1 | c.723C>T p.N241= | Silent (SNP) | VAF 76/161 reads (47%) | catalogued as rs1340270371, COSV60013622; called by muse, mutect2, varscan2
- GRIN2C | c.3522C>T p.H1174= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs751240915; called by muse, mutect2, varscan2
- GSDMA | c.756C>T p.D252= | Silent (SNP) | VAF 57/70 reads (81%) | catalogued as rs565172157; called by muse, mutect2, varscan2
- ILF3 | c.2211C>T p.H737= | Silent (SNP) | VAF 153/253 reads (60%) | catalogued as rs778107003; called by muse, mutect2, varscan2
- KMT2B | c.7920C>T p.D2640= | Silent (SNP) | VAF 82/214 reads (38%) | catalogued as rs770718510, COSV53075732; called by muse, varscan2
- LIPE | c.1035G>A p.A345= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as rs770239857, COSV54925637; called by muse, mutect2, varscan2
- LRRC14B | c.702C>A p.A234= | Silent (SNP) | VAF 12/157 reads (8%) | called by muse, mutect2
- LTBP3 | c.1455C>T p.D485= | Silent (SNP) | VAF 101/121 reads (83%) | catalogued as rs200551731; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEF2D | c.1356G>A p.A452= | Silent (SNP) | VAF 59/68 reads (87%) | catalogued as rs753692123, COSV61728564; called by muse, mutect2, varscan2
- MFAP2 | c.357C>T p.N119= | Silent (SNP) | VAF 69/89 reads (78%) | catalogued as rs369256913; called by muse, mutect2, varscan2
- MTBP | c.162T>C p.I54= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- MUC4 | c.1872A>G p.T624= | Silent (SNP) | VAF 117/279 reads (42%) | called by muse, mutect2
- NES | c.3303G>A p.P1101= | Silent (SNP) | VAF 44/48 reads (92%) | catalogued as rs753710930; called by muse, mutect2, varscan2
- NRCAM | c.2748G>A p.P916= (on ENST00000379028 / NM_001371124.1; = p.P900= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 94/176 reads (53%) | catalogued as rs1331489205, COSV61035887; called by muse, mutect2, varscan2
- OR4F15 | c.462C>T p.I154= | Silent (SNP) | VAF 48/173 reads (28%) | called by muse, mutect2, varscan2
- P2RX7 | c.1680C>A p.S560= | Silent (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- PABPC1L | c.1092C>T p.Y364= | Silent (SNP) | VAF 82/187 reads (44%) | catalogued as rs766822017; called by muse, mutect2, varscan2
- PBRM1 | c.4740A>T p.P1580= (on ENST00000296302 / NM_001366071.2; = p.P1473= on NM_018313.5) | Silent (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1725C>T p.G575= | Silent (SNP) | VAF 296/594 reads (50%) | catalogued as COSV100251286; called by mutect2, varscan2
- PHF3 | c.1431C>T p.S477= | Silent (SNP) | VAF 106/127 reads (83%) | catalogued as rs755735034; called by muse, mutect2, varscan2
- PKMYT1 | c.921C>T p.H307= | Silent (SNP) | VAF 117/151 reads (77%) | catalogued as rs371472836; called by muse, mutect2, varscan2
- PLEKHG6 | c.327G>A p.R109= | Silent (SNP) | VAF 73/169 reads (43%) | called by muse, mutect2, varscan2
- PPFIA4 | c.2053C>A p.R685= (on ENST00000447715; = p.R686= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/137 reads (80%) | called by muse, mutect2, varscan2
- PRL | c.102C>A p.G34= | Silent (SNP) | VAF 69/219 reads (32%) | catalogued as rs781674081, COSV60592324, COSV60593158; called by muse, mutect2, varscan2
- PRRC2B | c.1662C>A p.P554= | Silent (SNP) | VAF 18/289 reads (6%) | called by muse, mutect2
- PSAPL1 | c.177G>A p.A59= | Silent (SNP) | VAF 43/163 reads (26%) | catalogued as rs745451911, COSV59842696; called by muse, mutect2, varscan2
- PTPRS | c.1437C>T p.N479= | Silent (SNP) | VAF 43/55 reads (78%) | catalogued as rs1002891578, COSV53626191; called by muse, mutect2, varscan2
- RAE1 | c.204C>T p.C68= | Silent (SNP) | VAF 57/133 reads (43%) | called by muse, mutect2, varscan2
- RBBP4 | c.879A>G p.S293= | Silent (SNP) | VAF 76/88 reads (86%) | called by muse, varscan2
- SCN5A | c.3420C>T p.S1140= (on ENST00000333535 / NM_198056.3; = p.S1139= on NM_000335.5) | Silent (SNP) | VAF 57/143 reads (40%) | called by muse, mutect2, varscan2
- SELENOF | c.114G>A p.S38= | Silent (SNP) | VAF 71/82 reads (87%) | catalogued as rs967747988; called by muse, mutect2, varscan2
- SELENON | c.1311C>T p.F437= | Silent (SNP) | VAF 47/57 reads (82%) | catalogued as rs752908428, COSV62524320; called by muse, mutect2, varscan2
- SEMA6A | c.1506G>A p.A502= | Silent (SNP) | VAF 26/240 reads (11%) | catalogued as rs749668504, COSV56711206; called by muse, mutect2, varscan2
- SGMS1 | c.234C>T p.N78= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs776127190, COSV62369761; called by muse, mutect2, varscan2
- SGSH | c.267C>T p.Y89= | Silent (SNP) | VAF 45/49 reads (92%) | catalogued as rs1479456289; called by muse, mutect2, varscan2
- SLC22A3 | c.1413G>A p.S471= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as rs781070686, COSV51710111; called by muse, mutect2, varscan2
- SLC25A18 | c.639C>T p.N213= | Silent (SNP) | VAF 135/165 reads (82%) | catalogued as rs772306619; called by muse, mutect2, varscan2
- SLC30A6 | c.39C>T p.S13= | Silent (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- SLC5A4 | c.1965C>T p.H655= | Silent (SNP) | VAF 63/72 reads (88%) | catalogued as rs780626840, COSV56673839; called by muse, mutect2, varscan2
- SPAG5 | c.714C>T p.N238= | Silent (SNP) | VAF 55/67 reads (82%) | catalogued as rs958285122; called by muse, mutect2, varscan2
- SPTLC1 | c.1347G>A p.T449= | Silent (SNP) | VAF 76/180 reads (42%) | catalogued as rs749165047; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAB1 | c.4032G>A p.G1344= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- TDRD9 | c.2163T>C p.V721= | Silent (SNP) | VAF 35/43 reads (81%) | called by muse, mutect2, varscan2
- TMEM165 | c.549T>C p.P183= | Silent (SNP) | VAF 40/49 reads (82%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.219G>A p.P73= | Silent (SNP) | VAF 54/62 reads (87%) | catalogued as rs780909910, COSV54024687; called by muse, mutect2, varscan2
- TNXB | c.6237G>A p.P2079= (on ENST00000647633; = p.P1832= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as rs762597426, COSV100926810; called by muse, mutect2
- TRIM42 | c.1743C>T p.S581= | Silent (SNP) | VAF 70/199 reads (35%) | catalogued as COSV53887691, COSV99647834; called by muse, mutect2, varscan2
- TRIM55 | c.537C>T p.L179= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs772620946, COSV52550698; called by muse, mutect2, varscan2
- TTC16 | c.342C>T p.A114= | Silent (SNP) | VAF 81/182 reads (45%) | catalogued as rs753991892; called by muse, mutect2, varscan2
- UBR5 | c.5226G>A p.A1742= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs761737763, COSV99639226; called by muse, mutect2, varscan2
- UGGT1 | c.4533G>A p.P1511= | Silent (SNP) | VAF 42/234 reads (18%) | catalogued as rs1476377725; called by muse, mutect2, varscan2
- UNC5D | c.1995G>A p.A665= | Silent (SNP) | VAF 135/173 reads (78%) | catalogued as rs145027081, COSV54840707; called by muse, mutect2, varscan2
- VARS1 | c.3432C>T p.G1144= | Silent (SNP) | VAF 55/60 reads (92%) | catalogued as rs769749489; called by muse, mutect2, varscan2
- VWA2 | c.2061C>T p.H687= | Silent (SNP) | VAF 37/251 reads (15%) | catalogued as rs746639187; called by muse, mutect2, varscan2
- WNT16 | c.465C>T p.N155= (on ENST00000222462 / NM_057168.2; = p.N145= on NM_016087.2) | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as rs934853239; called by muse, mutect2
- ZNF445 | c.2784G>A p.P928= | Silent (SNP) | VAF 81/97 reads (84%) | catalogued as rs548627054, COSV101253700; called by muse, mutect2, varscan2
- FMN1 | c.2044-1716G>A | Intron (SNP) | VAF 9/68 reads (13%) | catalogued as rs760503752, COSV57917949; called by muse, mutect2, varscan2
- NACA | c.70+4672_70+4673del | Intron (DEL) | VAF 32/105 reads (30%) | called by pindel, varscan2
- NPR3 | c.*3387C>T | 3'UTR (SNP) | VAF 84/176 reads (48%) | called by muse, mutect2, varscan2
- TECR | chr19:14529575 G>A | 5'Flank (SNP) | VAF 59/158 reads (37%) | catalogued as COSV99295493; called by muse, mutect2, varscan2
